Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-AA52, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-AA52-01A (Primary Tumor).

Specimen ID	Lab Name	Specimen Type
	Histopathology	Histopathology

Specimen Comments

SPECIMEN

Bladder and prostate.

CLINICAL DETAILS

Invasive bladder cancer. Extensive desmoplastic reaction ?tumour.

MACROSCOPY

Cystoprostatectomy weighing 375 g. The prostate measures 25x43x32 mm. The bladder measures 55x70x65 mm. There is a ulcerated tumour at the posterior bladder wall. It measures 50 mm x 30 mm with a thickness of 23 mm with invasion of the bladder wall, but not obviously beyond into perivesical tissue. The tumour is close to the seminal vesicles and the posterior resection margin.

MICROSCOPY

The bladder contains an ulcerated poorly-differentiated micropapillary transitional cell carcinoma with lymphovascular and perineural invasion. The surface shows multinucleated giant cells amidst the granulation tissue. The tumour is confined to the posterior bladder wall. The tumour infiltrates beyond the muscularis propria of the posterior bladder wall with microscopic invasion of vesical fat and is 2 mm away from the deep posterior margin. The tumour has an accompanying fibrous response and abuts but does not invade the seminal vesicles or prostate. Two separate deposits of tumour are seen distant from the main mass, near the anterior wall.

The flat urothelium is not dysplastic.

See also for further information: both of the ureteric resections show no evidence of malignancy.

The prostate shows hyperplasia and no evidence of prostatic adenocarcinoma nor invasion by the bladder tumour.

SUMMARY

The features are those of a grade 3 transitional cell carcinoma of micropapillary type, pT3a Nx Mx.

Ref:

Pathologists -

CHF ICD O 3
path Carcinoma, urothelial NOS 8120/3
Carcinoma, transitional cell, micropapillary 8131/3
Site: Bladder, posterior wall C67.4
JW 4/30/14

Source: NCI Genomic Data Commons file 31a76a01-1060-4b9e-b694-ca2a343aa67a (TCGA-ZF-AA52.85DADBA7-A561-4282-B405-9906A8D3678E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).